Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB32, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB32-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:

with chest wall sarcoma.

Specimens Submitted:

- 1: Soft tissue, chest wall mass, right, radical resection
- 2: Soft tissue, chest wall mass, left, radical resection

DIAGNOSIS:

1. SOFT TISSUE, CHEST WALL MASS, RIGHT, RADICAL RESECTION:

- SCHWANNOMA.
- S-100 IMMUNOSTAIN IS POSITIVE.
- MARGINS ARE FREE OF TUMOR.
- ONE BENIGN LYMPH NODE.

2. SOFT TISSUE, CHEST WALL MASS, LEFT, RADICAL RESECTION:

- HIGH GRADE MYXOFIBROSARCOMA INVOLVING SKELETAL MUSCLE AND FIBROADIPOSE TISSUE.
- TUMOR MEASURES 5.4 CM GREATEST DIMENSION AND SHOWS ABOUT 20% NECROSIS.
- TUMOR IS 0.25 CM FROM THE DEEP, 0.2 CM FROM THE MEDIAL, 0.4 CM FROM THE INFERIOR, AND 0.6 CM FROM THE SUPERIOR MARGIN.
- CHANGES CONSISTENT WITH PRIOR BIOPSY.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	S-100	
	IMM RECUT	
	NEG CONT	

Gross Description:

** Continued on next page **

ICD O.3
Fibromyxosarcoma 8811/3
Site: Chest wall NOS C49.3
HJ 3/10/14

[page 2 of 3]
1.) The specimen is received fresh, labeled "radical resection of right chest wall mass including pectoralis major and minor, short stitch superior, long stitch lateral" and consists of an 18 x 11 x 6.5 cm fragment of soft fibrofatty tissue with attached skeletal muscle and 11.2 cm ellipse of skin.

Located on the superior portion is a round, grossly encapsulated, well circumscribed mass measuring 8.5 x 7 x 5 cm. Superior surface and is inked black; it is incised and TPS is taken. The cut surface of the mass is mostly solid with partially cystic areas. There are foci of hemorrhage and solid areas which have a variegated yellow-red-brown appearance. Interspersed within the tumor, there are blue-grey solid hard foci. The tumor is separated from the superior margin by a 0.2 cm strip of tissue and is 3 cm and 2.5 cm from the lateral and medial margins, respectively. The tumor is 2.1 cm from the posterior margin. The remaining portion of the specimen is inked as follows: lateral-yellow, posterior (deep)-green, medial-red and inferior-blue. Representative sections are taken. Pictures and TPS are taken.

Summary of Sections:

Rm- red margin
Gm- green margin
Bm- black margin
Blm- blue margin
Ym- yellow margin
S- skin
m- muscle
t- tumor

2) The specimen is received fresh, labeled "Radical resection of left chest wall mass short stitch superior long stitch lateral" and consists of a 14.0 x 11.0 x 5.0 cm portion of tan soft tissue, fatty tissue and skeletal muscle covered by an ellipse of tan-brown skin measuring 12.0 x 2.5 cm. The specimen is inked: deep margin-black, superior margin-yellow, medial margin-green, lateral margin-red, inferior margin-blue. Sections reveal a relatively well circumscribed, approximately spherical tan-yellow tumor with fibrotic foci, located within the skeletal muscle, measuring 5.4 x 5.2 x 5.2 cm. The tumor is located 0.2 cm from the deep and medial margins, 0.3 cm from the inferior margin, 0.5 cm from the superior margin, and over 1 cm from the lateral margin. The tumor is located 7.5 cm from the overlying skin. The specimen is photographed. Tissue is submitted to TPS. Representative sections are submitted.

Summary of sections:

TDM-tumor to deep margin
TMM-tumor to medial margin
TIM-tumor at inferior margin
SM-tumor at the superior margin
LM-lateral margin
T-tumor
SK-overlying skin

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Page 3 of 3

Summary of Sections:

Part 1: Soft tissue, chest wall mass, right, radical resection

Block	Sect.	Site	PCs
1		blm	1
1		bm	1
1		gm	1
1		m	1
1		rm	1
1		s	1
7		t	8
1		ym	1

Part 2: Soft tissue, chest wall mass, left, radical resection

Block	Sect.	Site	PCs
1		lm	1
2		sk	2
1		sm	1
3		t	3
1		tdm	1
1		tim	1
1		tmm	1

** End of Report **

Criteria	W 1/22/14	Yes	No
Dual/Synchronous Primary Noted	of left chest	✓	

Source: NCI Genomic Data Commons file 02cfd925-c2c7-4b0f-ad28-7e2b6ad2ae98 (TCGA-DX-AB32.CA2C84E3-432C-4ED1-830F-3671F8967E95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).